Somatic mutation profile of tumor specimen MMRF_1644_1_BM_CD138pos (aliquot MMRF_1644_1_BM_CD138pos_T1_KBS5U_L04313) from MMRF case MMRF_1644, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.3 years (30,775 days).
Specimen MMRF_1644_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa624fd4-1521-44b6-811a-b8fa790fe26c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1644_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1644_1_PB_Whole_C3_KBS5U_L04324; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1521004f-f639-4f03-bf87-5847b515c578

The open-access MAF lists 106 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, 3'UTR 24, Silent 13, Intron 13, 5'UTR 4, Nonsense Mutation 2, 3'Flank 2, Splice Site 1, Frame Shift Ins 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA4 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906771, CM104913; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 88/221 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, varscan2
- ABCA13 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs761223867; called by muse, mutect2, varscan2
- ANO5 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs750702622, COSV61082151; called by muse, mutect2, varscan2
- ASB9 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs758175142; called by muse, mutect2, varscan2
- BTG1 | c.13T>C p.Y5H | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.259); catalogued as rs890123202; called by muse, mutect2
- DPYSL3 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.199); catalogued as rs1461719288, COSV100575163; called by muse, mutect2, varscan2
- DUS2 | c.11A>T p.N4I | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV62707783; called by muse, mutect2, varscan2
- FHOD3 | c.3970G>A p.V1324M (on ENST00000359247 / NM_001281739.3; = p.V1341M on NM_025135.5) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs576568476, COSV57165501; called by muse, mutect2, varscan2
- IGHV2-70D | c.341A>T p.Y114F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1414572352; called by muse, varscan2
- IGLV4-3 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as rs375618475; called by muse, mutect2, varscan2
- KCNJ18 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as rs1278139238; called by muse, mutect2, varscan2
- LONRF2 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs751581769, COSV66539733; called by muse, mutect2, varscan2
- MAGEA12 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as rs1556833391, COSV100757077; called by muse, mutect2, varscan2
- SIPA1L2 | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs201808620; called by muse, mutect2, varscan2
- SPECC1L | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227709718; called by muse, mutect2, varscan2
- TDRD6 | c.4534A>C p.N1512H | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1231378726; called by muse, mutect2, varscan2
- TENM2 | c.5659G>A p.G1887R (on ENST00000518659 / NM_001122679.2; = p.G1648R on NM_001080428.3) | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.154); catalogued as rs758087653, COSV69122019; called by mutect2, varscan2
- TNIK | c.1043C>G p.S348W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as COSV52697020; called by muse, mutect2, varscan2
- TRRAP | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.899); catalogued as rs1562930647, COSV62851481; called by muse, mutect2, varscan2
- VRTN | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs773931361, COSV56443122; called by muse, mutect2, varscan2
- ADAMTS3 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AP1G2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by muse, varscan2
- BTG1 | c.15C>A p.Y5* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | called by muse, mutect2
- CFHR5 | c.1598C>A p.T533K | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COP1 | c.892-9_892-1del p.X298_splice | Splice Site (DEL) | VAF 12/62 reads (19%) | called by mutect2, varscan2
- DENND4C | c.763T>C p.F255L | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.5008C>A p.H1670N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- EPG5 | c.330A>T p.R110S | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- H3C2 | c.139_143dup p.L49Wfs*16 | Frame Shift Ins (INS) | VAF 40/110 reads (36%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); called by muse, mutect2
- HSPG2 | c.9199G>A p.V3067I | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- IGHV1-69D | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.259); called by mutect2, varscan2
- IGHV2-70D | c.241A>G p.S81G | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.165); called by muse, varscan2
- IGHV2-70D | c.95A>G p.K32R | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGHV3-73 | c.224A>C p.N75T | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGLV4-3 | c.92C>A p.A31D | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- MCF2L | c.1750G>A p.G584S (on ENST00000375608; = p.G552S on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MCL1 | c.418G>A p.V140I | Missense Mutation (SNP) | VAF 82/266 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MSN | c.1514A>T p.E505V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PACSIN1 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- PAXIP1 | c.251C>A p.T84N | Missense Mutation (SNP) | VAF 139/293 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- RGS1 | c.257T>A p.L86Q | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SNX1 | c.1220G>C p.R407P | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STAT5B | c.1724A>G p.D575G | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.972); called by muse, mutect2
- TENM2 | c.6146T>C p.L2049S (on ENST00000518659 / NM_001122679.2; = p.L1810S on NM_001080428.3) | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- USP19 | c.2075C>G p.P692R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF77 | c.1144T>G p.C382G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9orf131 | c.2124T>C p.N708= | Silent (SNP) | VAF 62/193 reads (32%) | catalogued as rs750188696; called by muse, mutect2, varscan2
- CTAG2 | c.333G>T p.R111= | Silent (SNP) | VAF 59/198 reads (30%) | called by muse, mutect2, varscan2
- DEFB104A | c.16C>T p.L6= | Silent (SNP) | VAF 39/61 reads (64%) | called by muse, mutect2, varscan2
- EHD3 | c.930C>T p.I310= | Silent (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- GLB1L2 | c.783C>G p.T261= | Silent (SNP) | VAF 40/74 reads (54%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.339G>A p.T113= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs376111067; called by muse, varscan2
- IGLL5 | c.81G>A p.L27= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs56055217, COSV73249379; called by muse, mutect2, varscan2
- IQCF5 | c.342C>A p.G114= | Silent (SNP) | VAF 88/176 reads (50%) | called by muse, mutect2, varscan2
- KAT6A | c.5256C>T p.S1752= | Silent (SNP) | VAF 30/60 reads (50%) | called by muse, mutect2, varscan2
- KIDINS220 | c.1500C>T p.L500= | Silent (SNP) | VAF 45/81 reads (56%) | called by muse, mutect2, varscan2
- PSMD8 | c.135C>T p.S45= | Silent (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- SLAMF9 | c.531T>C p.Y177= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as rs1236402162; called by muse, mutect2, varscan2
- TTN | c.1953C>T p.A651= (on ENST00000591111; = p.A605= on NM_003319.4) | Silent (SNP) | VAF 47/99 reads (47%) | catalogued as rs778742098, COSV59983791; ClinVar: likely benign; called by muse, mutect2, varscan2
- AGMO | c.1263+7147C>T | Intron (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- ALDH8A1 | c.*785T>G | 3'UTR (SNP) | VAF 61/124 reads (49%) | called by muse, mutect2, varscan2
- APLN | c.*1197C>A | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- AR | c.*4992G>A | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*84A>G | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- ARMCX2 | c.*13C>T | 3'UTR (SNP) | VAF 20/44 reads (45%) | catalogued as rs936777363; called by muse, mutect2, varscan2
- ATP11C | c.*1077A>T | 3'UTR (SNP) | VAF 26/83 reads (31%) | called by muse, mutect2, varscan2
- B3GALT5 | c.*621C>T | 3'UTR (SNP) | VAF 23/55 reads (42%) | catalogued as rs565329913; called by muse, mutect2, varscan2
- BCKDK | c.*164C>T | 3'UTR (SNP) | VAF 51/107 reads (48%) | called by muse, mutect2, varscan2
- CBLN4 | c.-826G>A | 5'UTR (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- COP1 | c.-27C>T | 5'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- CRYBG1 | c.*1884T>C | 3'UTR (SNP) | VAF 33/69 reads (48%) | called by muse, mutect2, varscan2
- DMTF1 | c.2029-13T>A | Intron (SNP) | VAF 21/44 reads (48%) | catalogued as COSV57538369; called by muse, mutect2, varscan2
- HDAC11 | c.*146C>T | 3'UTR (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- HSD17B12 | c.*1049A>C | 3'UTR (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- KCNA2 | c.*9186C>G | 3'UTR (SNP) | VAF 21/40 reads (53%) | catalogued as rs912396392; called by muse, mutect2, varscan2
- KCNMA1 | c.2266+6039T>C | Intron (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- KIF23 | c.2796+39T>C | Intron (SNP) | VAF 45/136 reads (33%) | called by muse, mutect2, varscan2
- LAMP2 | c.1093+2822A>C | Intron (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- LINC00470 | n.1361-2512C>G | Intron (SNP) | VAF 20/46 reads (43%) | called by muse, mutect2, varscan2
- LINC00535 | n.1134-29633G>C | Intron (SNP) | VAF 47/98 reads (48%) | called by muse, mutect2, varscan2
- NGDN | chr14:23478513 T>C | 3'Flank (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- NOP9 | c.-36G>A | 5'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs1420080867; called by muse, mutect2, varscan2
- NUDT16 | c.*4260G>A | 3'UTR (SNP) | VAF 23/48 reads (48%) | catalogued as rs969357093; called by muse, mutect2, varscan2
- OR2H1 | c.*14-115G>A | Intron (SNP) | VAF 15/36 reads (42%) | catalogued as rs191079256, COSV101009793; called by muse, mutect2, varscan2
- PARP9 | c.2185+690G>A | Intron (SNP) | VAF 30/70 reads (43%) | catalogued as rs1472094860; called by muse, mutect2, varscan2
- PCMTD1 | c.*1545A>G | 3'UTR (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- PPFIBP2 | chr11:7655476 C>T | 3'Flank (SNP) | VAF 53/101 reads (52%) | called by muse, mutect2, varscan2
- PRLR | c.*8775C>G | 3'UTR (SNP) | VAF 10/39 reads (26%) | called by mutect2, varscan2
- PSMG1 | c.134+70_134+76del | Intron (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PXYLP1 | c.79+2448G>C | Intron (SNP) | VAF 174/370 reads (47%) | called by mutect2, varscan2
- RAB3C | c.*1581A>G | 3'UTR (SNP) | VAF 47/146 reads (32%) | called by muse, mutect2, varscan2
- RNF128 | c.*905A>G | 3'UTR (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49892160 G>A | 5'Flank (SNP) | VAF 59/59 reads (100%) | called by muse, mutect2, varscan2
- SAT1 | c.-149T>G | 5'UTR (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- SH2D1B | c.*896T>A | 3'UTR (SNP) | VAF 30/94 reads (32%) | called by muse, mutect2, varscan2
- SIRPA | c.-9-9G>C | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1329008812; called by muse, varscan2
- SPOCK2 | c.*1865G>A | 3'UTR (SNP) | VAF 18/62 reads (29%) | catalogued as rs1035915739; called by muse, mutect2, varscan2
- SSPOP | n.10838C>A | RNA (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- STAMBP | c.*3629A>G | 3'UTR (SNP) | VAF 46/79 reads (58%) | catalogued as rs971628638; called by muse, mutect2, varscan2
- STMN2 | c.*713C>G | 3'UTR (SNP) | VAF 173/345 reads (50%) | called by muse, mutect2, varscan2
- SVIP | c.*3415T>C | 3'UTR (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- TBC1D12 | c.*448A>T | 3'UTR (SNP) | VAF 39/111 reads (35%) | called by muse, mutect2, varscan2
- TNPO2 | c.*1851_*1869del | 3'UTR (DEL) | VAF 26/55 reads (47%) | called by mutect2, pindel, varscan2
- VAMP1 | c.129+61A>G | Intron (SNP) | VAF 52/116 reads (45%) | called by muse, mutect2, varscan2
